Gene-level copy-number profile of tumor specimen TCGA-EK-A2RM-01A from TCGA case TCGA-EK-A2RM, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 40.6 years (14,842 days).
Specimen TCGA-EK-A2RM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.02215c58-6fca-44ab-b81b-c5c11bd3fb49.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,488 have no estimate.
https://portal.gdc.cancer.gov/files/9c1a1899-249b-450c-9f89-604988a38a2b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 4; copy number 2: 15,201; copy number 3: 14,263; copy number 4: 16,245; copy number 5: 5,441; copy number 6: 2,492; copy number 7: 1,489.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EK-A2RM-01A-21D-A18H-01): tumor purity 0.65, ploidy 3.51, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
